Somatic mutation profile of tumor specimen ALCH-AEYV-TTR1-A (aliquot ALCH-AEYV-TTR1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-AEYV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.9 years (23,348 days).
Specimen ALCH-AEYV-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51446116-40b4-4730-9f0b-06a8e8ca9df8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEYV-NB1-A (Blood Derived Normal), aliquot ALCH-AEYV-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/702071b0-b1cb-450f-aebd-09f37fe52927

The open-access MAF lists 1,123 somatic variants for this specimen: 762 protein-altering or splice-affecting, 203 silent, 158 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 662, Silent 203, Intron 75, Nonsense Mutation 41, 3'UTR 24, RNA 23, Frame Shift Del 21, Splice Site 20, 5'UTR 15, 5'Flank 14, Splice Region 8, Frame Shift Ins 7.

Variants (750 of 1,123; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 61/567 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs756407851, COSV63973789; called by muse, mutect2, varscan2
- AFF2 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV54009503; called by muse, mutect2, varscan2
- AKR1D1 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 49/335 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54338706; called by muse, mutect2, varscan2
- ALOX15B | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs751641286, COSV101205682; called by muse, mutect2, varscan2
- ANKRD35 | c.1535C>A p.A512D | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62911812; called by muse, mutect2, varscan2
- ANKRD36 | c.1035-1G>A p.X345_splice | Splice Site (SNP) | VAF 14/115 reads (12%) | catalogued as rs1348399315; called by muse, mutect2, varscan2
- APEH | c.870del p.K291Sfs*17 | Frame Shift Del (DEL) | VAF 44/268 reads (16%) | catalogued as rs768993340, COSV56533158; called by mutect2, pindel, varscan2
- APLNR | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.109); catalogued as COSV57242652; called by muse, mutect2, varscan2
- APOH | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as COSV52772623; called by muse, mutect2, varscan2
- ARFIP2 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs750272738, COSV54446738; called by muse, mutect2, varscan2
- ARHGAP29 | c.3598G>T p.G1200C | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.366); catalogued as COSV99558560; called by muse, mutect2, varscan2
- ARHGEF17 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs762157933; called by muse, mutect2, varscan2
- ARMC4 | c.3034A>G p.M1012V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs1331252892; called by muse, mutect2, varscan2
- ARMC4 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as rs199511486, COSV59474260; called by muse, mutect2
- BCORL1 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99499121, COSV99500505; called by muse, mutect2, varscan2
- BRWD3 | c.5116G>T p.G1706W | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV64745635; called by muse, mutect2, varscan2
- C1QTNF3 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV51467798, COSV51468513; called by muse, mutect2, varscan2
- CACNA1E | c.4393C>A p.H1465N | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV62442969; called by mutect2, varscan2
- CBLIF | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 68/599 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57238504, COSV57239133; called by muse, mutect2, varscan2
- CCDC168 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 15/114 reads (13%) | catalogued as COSV70555871; called by muse, mutect2
- CCDC178 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV55773032; called by muse, varscan2
- CCDC74A | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 52/676 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV54608850; called by muse, mutect2
- CCDC85A | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759658736; called by muse, mutect2, varscan2
- CCNB3 | c.3847C>A p.R1283S | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52072063; called by muse, mutect2, varscan2
- CCT8L2 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV63462855; called by muse, mutect2, varscan2
- CDH10 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.062); catalogued as COSV99077797; called by muse, mutect2, varscan2
- CDH10 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as COSV100049919, COSV52591381; called by muse, mutect2
- CDH18 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV56957699, COSV56962750; called by muse, varscan2
- CDH18 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766286596, COSV56963540; called by muse, varscan2
- CDS2 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs1411421408; called by muse, mutect2, varscan2
- CECR2 | c.618dup p.R207Tfs*12 (on ENST00000342247 / NM_001290047.2; = p.R44Tfs*12 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 15/137 reads (11%) | catalogued as COSV52847756; called by pindel, varscan2
- CEP126 | c.702G>T p.L234F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs1180190723; called by muse, mutect2
- CEP135 | c.1111-2A>T p.X371_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as rs373490268; called by mutect2, varscan2
- CEP57L1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs1045910109; called by muse, varscan2
- CHRM3 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 38/473 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs768096500; called by muse, mutect2
- CHST6 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs776030874, CD066352; called by muse, mutect2, varscan2
- CLDN16 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 39/373 reads (10%) | catalogued as rs753901053, CM146204, COSV53228073; called by muse, mutect2, varscan2
- CLEC5A | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1487774670, COSV69397332; called by muse, varscan2
- CLIP2 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56281103; called by muse, mutect2, varscan2
- CMKLR1 | c.379G>A p.V127I (on ENST00000312143 / NM_001142344.2; = p.V125I on NM_004072.3) | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs374487323; called by muse, mutect2, varscan2
- CNGA2 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV100323528; called by muse, mutect2, varscan2
- CNTNAP5 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV70510200; called by muse, mutect2, varscan2
- CSMD3 | c.4661G>T p.C1554F (on ENST00000297405 / NM_001363185.1; = p.C1450F on NM_052900.3) | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52193765; called by muse, mutect2, varscan2
- CST1 | c.342+1G>T p.X114_splice | Splice Site (SNP) | VAF 30/233 reads (13%) | catalogued as rs772181608; called by muse, mutect2, varscan2
- CT55 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as COSV52278148, COSV99358770; called by muse, mutect2
- CT55 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99358844; called by muse, mutect2
- CTNNA2 | c.1291-2A>T p.X431_splice | Splice Site (SNP) | VAF 21/128 reads (16%) | catalogued as COSV58149589; called by muse, mutect2, varscan2
- DAPK1 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV63788317; called by muse, mutect2, varscan2
- DCT | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297582042; called by muse, mutect2, varscan2
- DGCR8 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV61225545; called by muse, mutect2, varscan2
- DIDO1 | c.5165A>G p.D1722G | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56612904; called by muse, mutect2
- DLEC1 | c.1917T>A p.A639= | Splice Region (SNP) | VAF 21/89 reads (24%) | catalogued as rs1388028094; called by muse, mutect2, varscan2
- DNAH17 | c.8115G>T p.L2705F | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1022814764; called by muse, mutect2, varscan2
- DOCK11 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV52244637; called by muse, mutect2, varscan2
- DOK1 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 70/468 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV99283930; called by muse, mutect2, varscan2
- EQTN | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV66219232; called by muse, mutect2, varscan2
- ERICH3 | c.3731C>A p.A1244E | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV58601622; called by muse, mutect2, varscan2
- FAM149B1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs998438882; called by muse, mutect2, varscan2
- FAP | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51868994; called by muse, mutect2
- FAT2 | c.10480C>T p.Q3494* | Nonsense Mutation (SNP) | VAF 66/334 reads (20%) | catalogued as rs1384482503; called by muse, mutect2, varscan2
- FBXO40 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573344, COSV57521872, COSV57525984; called by muse, mutect2, varscan2
- FER | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 17/112 reads (15%) | catalogued as COSV99812095; called by muse, mutect2, varscan2
- FGGY | c.996C>G p.S332R | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58025280; called by muse, mutect2, varscan2
- GABRA2 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.973); catalogued as rs773130859, COSV62917254; called by muse, mutect2, varscan2
- GALNT17 | c.960C>T p.I320= | Splice Region (SNP) | VAF 35/162 reads (22%) | catalogued as COSV100352575, COSV61192457; called by muse, mutect2, varscan2
- GALR1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1241994306; called by muse, mutect2, varscan2
- GCNA | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 60/506 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.134); catalogued as rs768390777; called by muse, varscan2
- GDPD2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs910630290, COSV65533888; called by muse, mutect2, varscan2
- GDPD4 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV60021022; called by muse, mutect2, varscan2
- GGT7 | c.1791C>G p.H597Q | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60542655; called by muse, mutect2, varscan2
- GINS1 | c.525C>G p.H175Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52466839; called by muse, mutect2, varscan2
- GJA8 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV53789718; called by muse, mutect2
- GPR63 | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99038572; called by muse, mutect2, varscan2
- GPRASP2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV59991164; called by muse, mutect2, varscan2
- GRM7 | c.1157C>G p.T386R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.351); catalogued as rs754368541, COSV100735945; called by muse, mutect2, varscan2
- GRXCR1 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 71/311 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV67673614; called by muse, mutect2, varscan2
- GUCA2B | c.318del p.A107Rfs*70 | Frame Shift Del (DEL) | VAF 46/368 reads (13%) | catalogued as COSV65368226; called by mutect2, pindel, varscan2
- H2BC6 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61591306; called by muse, mutect2, varscan2
- H4C12 | c.224A>C p.E75A | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV104423272; called by muse, mutect2, varscan2
- HCN1 | c.2035C>A p.H679N | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100298723; called by muse, mutect2, varscan2
- HDX | c.1198C>G p.H400D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV52973097, COSV52981752; called by muse, mutect2
- HERC5 | c.2187C>G p.F729L | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52038738; called by muse, mutect2
- HMCES | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.09); catalogued as COSV101077175; called by muse, mutect2, varscan2
- HMGCS2 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 88/585 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as rs757083410; called by muse, mutect2, varscan2
- HNF4G | c.95G>T p.C32F (on ENST00000354370 / NM_001330561.2; = p.C79F on NM_004133.5) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62966307, COSV62974387; called by muse, mutect2, varscan2
- IFNA17 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV69738174; called by muse, mutect2, varscan2
- IPO13 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs769331497; called by muse, mutect2, varscan2
- IRF4 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV66706790; called by muse, mutect2, varscan2
- ITGA8 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100959343; called by muse, mutect2, varscan2
- KLHL28 | c.1441A>T p.I481F | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100753204; called by muse, mutect2, varscan2
- KNL1 | c.5480A>T p.D1827V (on ENST00000346991 / NM_170589.5; = p.D1801V on NM_144508.5) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV61161177; called by muse, mutect2
- KRTAP10-10 | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs782232975; called by muse, mutect2, varscan2
- L1CAM | c.2384del p.G795Afs*56 | Frame Shift Del (DEL) | VAF 19/130 reads (15%) | catalogued as CM138912; called by mutect2, pindel, varscan2
- LRIT1 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1212136357; called by muse, mutect2, varscan2
- LRP1B | c.10628G>T p.G3543V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV67190620, COSV67195050; called by muse, mutect2, varscan2
- LRRK2 | c.6771C>A p.S2257R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs200300610; called by muse, mutect2, varscan2
- MAB21L3 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 59/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101046358, COSV65673881; called by muse, mutect2, varscan2
- MAOA | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58645573; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV61010051; called by muse, mutect2, varscan2
- MAP2 | c.4264C>T p.L1422F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52309759; called by muse, mutect2, varscan2
- MAP3K1 | c.964A>C p.I322L | Missense Mutation (SNP) | VAF 68/478 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV68128783; called by muse, mutect2, varscan2
- MGAM | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 26/325 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101516545; called by muse, mutect2
- MIB2 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV61757517; called by muse, mutect2, varscan2
- MKRN3 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091841; called by muse, mutect2, varscan2
- MKX | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1330854930; called by muse, mutect2, varscan2
- MMP16 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54170667; called by muse, mutect2, varscan2
- MS4A4A | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV59701616; called by muse, mutect2, varscan2
- MUC16 | c.7877C>A p.P2626H | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101200836, COSV101202216; called by muse, mutect2, varscan2
- MYF5 | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57356108; called by muse, mutect2, varscan2
- NANOS2 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs752417445; called by muse, mutect2, varscan2
- NAP1L2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs1394206855, COSV65172543; called by muse, mutect2, varscan2
- NBAS | c.3790G>T p.G1264C | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV99870788; called by muse, mutect2, varscan2
- NDST4 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV52137099; called by muse, mutect2, varscan2
- NDUFA9 | c.987G>C p.L329F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV99865609; called by muse, mutect2
- NEB | c.14473G>T p.D4825Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201731351; called by muse, varscan2
- NIPBL | c.1721A>G p.N574S | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.073); catalogued as rs144289137; ClinVar: uncertain significance; called by muse, mutect2
- NISCH | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.346); catalogued as rs370428956, COSV100617033; called by muse, mutect2, varscan2
- NKAIN4 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64785830; called by muse, varscan2
- NLRP4 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769100642; called by muse, mutect2, varscan2
- NOS1AP | c.274C>A p.L92I | Missense Mutation (SNP) | VAF 46/437 reads (11%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.973); catalogued as COSV62633628; called by muse, mutect2, varscan2
- NPRL3 | c.853G>A p.V285M (on ENST00000611875 / NM_001077350.3; = p.V260M on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); catalogued as rs373936494; called by muse, mutect2, varscan2
- NRXN2 | c.3922G>T p.G1308C | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99635529; called by muse, mutect2, varscan2
- NUGGC | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754104946, COSV58439494; called by muse, mutect2, varscan2
- ODF3L2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs1347998190; called by muse, mutect2, varscan2
- OR10G8 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV70908423; called by muse, mutect2, varscan2
- OR13C2 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV73377771; called by muse, mutect2, varscan2
- OR14K1 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV51721143, COSV99315167; called by muse, mutect2, varscan2
- OR2M2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs767241426; called by muse, mutect2, varscan2
- OR5AP2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57259000; called by muse, mutect2, varscan2
- OR5M10 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV73242333, COSV73242415; called by muse, mutect2, varscan2
- OR6Q1 | c.919C>G p.R307G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV56932017; called by muse, mutect2
- OR7C1 | c.588C>A p.N196K | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV50183954; called by muse, mutect2, varscan2
- OTOG | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.73); catalogued as rs1299008272; called by muse, mutect2
- PCDHB2 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs569244465, COSV50564827; called by muse, mutect2, varscan2
- PDZD3 | c.982C>A p.R328S (on ENST00000531114; = p.R248S on NM_024791.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52709297; called by muse, mutect2, varscan2
- PHYHIPL | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749912782, COSV65849642, COSV65849663; called by muse, mutect2, varscan2
- PKD2L1 | c.2259A>T p.Q753H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV100559475; called by muse, mutect2
- PKHD1L1 | c.2949C>A p.Y983* | Nonsense Mutation (SNP) | VAF 56/390 reads (14%) | catalogued as COSV65745458; called by muse, varscan2
- PKHD1L1 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775782360, COSV65742042; called by muse, varscan2
- POF1B | c.1165-1G>T p.X389_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53139905; called by muse, varscan2
- POM121L12 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV68692700; called by muse, mutect2, varscan2
- PPP1R37 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55523744; called by muse, mutect2, varscan2
- PTGER2 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1566494263; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.679C>T p.R227W (on ENST00000421990 / NM_001136042.2; = p.R209W on NM_025267.3) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs370867262, COSV64183457; called by muse, mutect2
- PTPRN2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs756456532; called by muse, mutect2, varscan2
- RASA1 | c.1050-1G>A p.X350_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as COSV57203182, COSV99169670; called by muse, mutect2
- RB1CC1 | c.2929A>T p.R977W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV99209304; called by muse, mutect2
- RBMXL2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs1462823546, COSV100182042; called by muse, mutect2, varscan2
- RGL1 | c.1510G>C p.A504P (on ENST00000360851 / NM_001297672.2; = p.A539P on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV58984684; called by muse, mutect2, varscan2
- RGS7 | c.265G>C p.G89R | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100464718; called by muse, mutect2, varscan2
- RHCG | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189423740; called by muse, mutect2, varscan2
- RIMS2 | c.3731C>G p.A1244G | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV51721722; called by muse, mutect2, varscan2
- ROS1 | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV63863209; called by muse, mutect2, varscan2
- RPA4 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs372688483; called by muse, mutect2, varscan2
- RUBCNL | c.1457T>C p.V486A | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100529021; called by muse, mutect2, varscan2
- RYR1 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as rs757600766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.7590G>A p.M2530I | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1159462432; called by muse, mutect2, varscan2
- RYR2 | c.2048A>C p.E683A | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs769268535; called by muse, mutect2
- RYR2 | c.3215C>A p.A1072E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as COSV100773308; called by muse, mutect2, varscan2
- RYR2 | c.6568C>A p.P2190T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1558103839, COSV63704649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51762761; called by muse, mutect2, varscan2
- SAMD9L | c.4680G>T p.R1560S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV59081770; called by muse, mutect2, varscan2
- SAMD9L | c.4679G>T p.R1560M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as rs1269649126, COSV100560366; called by muse, mutect2, varscan2
- SATL1 | c.494C>G p.P165R (on ENST00000395409; = p.P352R on NM_001012980.2) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100260678; called by muse, mutect2
- SDCCAG8 | c.740+6G>T | Splice Region (SNP) | VAF 23/208 reads (11%) | catalogued as COSV59406230; called by muse, mutect2, varscan2
- SEC23A | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100305654, COSV56977390; called by muse, mutect2, varscan2
- SEZ6 | c.1996C>A p.R666S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.373); catalogued as rs749356911, COSV100252557; called by muse, mutect2
- SH3GL2 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1340537811; called by muse, mutect2
- SH3KBP1 | c.1103G>T p.R368I | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751733126, COSV101114987; called by muse, mutect2, varscan2
- SHANK3 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104393363; called by muse, mutect2, varscan2
- SIGLEC7 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58316053, COSV58317771; called by muse, mutect2
- SLAMF6 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100924813; called by muse, mutect2
- SLC12A1 | c.286T>A p.Y96N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs773795619; called by muse, mutect2, varscan2
- SLC13A2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782296247, COSV58993901; called by muse, mutect2
- SLC22A6 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758523049; called by muse, mutect2, varscan2
- SLC35A5 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV53727642; called by muse, mutect2, varscan2
- SLC44A5 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100900951; called by muse, mutect2
- SLCO2A1 | c.235-1G>C p.X79_splice | Splice Site (SNP) | VAF 27/126 reads (21%) | catalogued as CS1312333, COSV60485665; called by muse, mutect2, varscan2
- SMARCA4 | c.2936G>T p.R979L | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100758931, COSV60787151; called by muse, mutect2, varscan2
- SNAP91 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52128396; called by muse, mutect2, varscan2
- SNX14 | c.2175C>G p.I725M (on ENST00000314673 / NM_001350535.1; = p.I672M on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV59010393; called by muse, mutect2, varscan2
- SOWAHD | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 26/210 reads (12%) | catalogued as COSV100673187; called by muse, mutect2, varscan2
- SPATA6 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as rs201878636, COSV100892992; called by muse, mutect2, varscan2
- SPIDR | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554696205, COSV52383077; called by muse, varscan2
- SSTR3 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1054188776, COSV100142674; called by muse, mutect2, varscan2
- STARD8 | c.1674G>T p.R558S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV52924362; called by muse, mutect2, varscan2
- TAF15 | c.1592A>G p.Y531C (on ENST00000605844 / NM_139215.3; = p.Y528C on NM_003487.4) | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs750426077; called by muse, mutect2, varscan2
- TBC1D10C | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs576906702; called by muse, mutect2, varscan2
- TBC1D32 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51544563; called by muse, mutect2
- TBKBP1 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766963939; called by muse, mutect2, varscan2
- TCTE1 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV101025441; called by muse, mutect2, varscan2
- TENM1 | c.2455G>T p.D819Y | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100951379; called by muse, mutect2
- TEX13C | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 64/478 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.587); catalogued as rs1232155117; called by muse, varscan2
- TGFBR2 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM060085, CM086981, COSV55445539, COSV55457221; called by muse, mutect2, varscan2
- THSD7A | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 30/266 reads (11%) | catalogued as COSV70271745; called by muse, mutect2, varscan2
- THSD7B | c.3298G>T p.G1100C (on ENST00000272643; = p.G1098C on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV55745872; called by muse, mutect2
- THSD7B | c.4382G>T p.G1461V (on ENST00000272643; = p.G1459V on NM_001316349.2) | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99751697; called by muse, mutect2, varscan2
- TMEM100 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV70117964; called by mutect2, varscan2
- TMEM132D | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs750720403; called by muse, varscan2
- TMEM132D | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 66/228 reads (29%) | catalogued as COSV101396633, COSV101399631, COSV70602045; called by muse, mutect2, varscan2
- TMEM132D | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 67/370 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs765486372, COSV70602264; called by muse, mutect2, varscan2
- TMPRSS7 | c.924C>A p.D308E (on ENST00000452346; = p.D182E on NM_001042575.2) | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756782875; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2449G>T p.V817L | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs953590078; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 68/196 reads (35%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRABD2A | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs1308767109; called by muse, varscan2
- TRAF3IP1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs201250604, COSV64853311, COSV64854068, COSV64854253; called by muse, mutect2, varscan2
- TRIM42 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV53881155; called by muse, mutect2, varscan2
- TSEN34 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs373921569; called by muse, mutect2, varscan2
- TTI1 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs757824954; called by muse, mutect2, varscan2
- TTN | c.54967G>A p.E18323K (on ENST00000591111; = p.E10899K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | PolyPhen possibly damaging (0.814); catalogued as rs918361300; called by muse, varscan2
- TTN | c.22943A>G p.N7648S (on ENST00000591111; = p.N6721S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs794729630; ClinVar: uncertain significance; called by muse, mutect2
- UNC80 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV99781461; called by muse, mutect2, varscan2
- USH2A | c.12473A>T p.Q4158L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs780213108; called by muse, mutect2, varscan2
- VNN1 | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 23/181 reads (13%) | catalogued as COSV63390254; called by muse, mutect2, varscan2
- VPS13C | c.6392C>T p.S2131L (on ENST00000644861 / NM_020821.3; = p.S2088L on NM_017684.5) | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs755887725; called by muse, mutect2, varscan2
- VPS33B | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 68/496 reads (14%) | catalogued as COSV100325710; called by muse, mutect2, varscan2
- WDR13 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54332277; called by muse, mutect2, varscan2
- XIRP2 | c.5204C>G p.T1735R (on ENST00000628543; = p.T1910R on NM_152381.6) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV54735452; called by muse, mutect2, varscan2
- XPNPEP2 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.075); catalogued as rs996964281; called by muse, mutect2
- YIPF1 | c.124G>C p.G42R | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs369587889; called by muse, mutect2, varscan2
- ZC3H12B | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV59053221; called by muse, mutect2, varscan2
- ZEB1 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV58053262; called by muse, mutect2, varscan2
- ZFP2 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63725376, COSV63725784; called by muse, varscan2
- ZNF469 | c.8793C>A p.S2931R (on ENST00000437464; = p.S2959R on NM_001367624.2) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV71258184; called by muse, mutect2, varscan2
- ZNF502 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as COSV56073633; called by muse, mutect2
- ZNF648 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 109/469 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60570154; called by muse, mutect2, varscan2
- ZNF653 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | catalogued as COSV53404591; called by muse, mutect2, varscan2
- ZNF677 | c.495T>A p.F165L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61720910; called by muse, mutect2, varscan2
- ZNF679 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55376683; called by muse, varscan2
- ZNF81 | c.991A>T p.I331L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV58575413; called by muse, mutect2
- ZNF81 | c.1826C>G p.P609R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58578630; called by muse, mutect2, varscan2
- A1BG | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA10 | c.2803G>T p.G935W | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2
- ABCA12 | c.1832C>T p.T611I (on ENST00000272895 / NM_173076.3; = p.T293I on NM_015657.3) | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB5 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC100868.1 | c.1838T>C p.M613T | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ACE2 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2
- ACLY | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ACMSD | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ACSM4 | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ACSM5 | c.1462del p.E488Kfs*27 | Frame Shift Del (DEL) | VAF 50/300 reads (17%) | called by mutect2, pindel, varscan2
- ACTC1 | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ACTG1 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTR10 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.339); called by muse, mutect2
- ADAD1 | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- ADAM2 | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- ADAM23 | c.2414C>G p.A805G | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ADAMTS10 | c.3043-1G>A p.X1015_splice | Splice Site (SNP) | VAF 24/84 reads (29%) | called by mutect2, varscan2
- ADCY4 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ADCY5 | c.1590G>T p.R530S | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- AFF2 | c.1472A>T p.E491V | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AGFG1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ALK | c.4750T>C p.Y1584H | Missense Mutation (SNP) | VAF 55/632 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMY1A | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ANK2 | c.4418C>A p.S1473* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- ANK2 | c.8414C>A p.P2805Q | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKFN1 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ANKLE2 | c.645G>C p.R215S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ANTXRL | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ANXA7 | c.1202G>T p.G401V (on ENST00000372919 / NM_001320880.2; = p.G379V on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP2A1 | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP4E1 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- APOBEC3D | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ARHGAP29 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGEF10L | c.3728G>T p.G1243V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF11 | c.2633A>T p.E878V | Missense Mutation (SNP) | VAF 115/377 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX1 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); called by muse, mutect2
- ARMCX4 | c.672_673del p.A225Wfs*13 (on ENST00000433011; = p.A121Wfs*13 on NM_001256155.2) | Frame Shift Del (DEL) | VAF 27/291 reads (9%) | called by mutect2, pindel*
- ARMCX5-GPRASP2 | c.251C>A p.A84D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ARPP21 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 24/159 reads (15%) | called by muse, varscan2
- ARSI | c.1576G>C p.D526H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ASAH2 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASIC2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ASMTL | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATP13A3 | c.2346del p.V784Lfs*4 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- ATP7A | c.2375C>A p.A792E | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATRNL1 | c.3290A>G p.Y1097C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRX | c.6205C>G p.L2069V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.041); called by muse, varscan2
- BCOR | c.3304G>T p.V1102L | Missense Mutation (SNP) | VAF 61/333 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND7 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BET1 | c.36dup p.G13Wfs*10 | Frame Shift Ins (INS) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- BGN | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BLVRA | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 65/428 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BNC2 | c.1963G>T p.D655Y | Missense Mutation (SNP) | VAF 95/487 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- BRCA1 | c.3297dup p.G1100Wfs*3 | Frame Shift Ins (INS) | VAF 14/113 reads (12%) | called by mutect2, pindel, varscan2
- BRCA2 | c.3616G>T p.G1206C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.917); called by muse, mutect2
- BRWD3 | c.1809del p.L604Wfs*27 | Frame Shift Del (DEL) | VAF 22/215 reads (10%) | called by mutect2, pindel, varscan2
- C10orf71 | c.4073C>A p.P1358H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf167 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- C4orf54 | c.3416C>A p.S1139Y | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- C7 | c.962C>A p.S321* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- CACNA1E | c.4728G>T p.K1576N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CACNA1E | c.4729C>T p.L1577F | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNG7 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASP8AP2 | c.1112A>T p.K371I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CCDC14 | c.2610C>A p.D870E (on ENST00000488653; = p.D822E on NM_022757.5) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CCDC158 | c.2357dup p.N786Kfs*23 | Frame Shift Ins (INS) | VAF 24/191 reads (13%) | called by mutect2, varscan2
- CCDC39 | c.1847A>T p.Y616F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.029); called by muse, varscan2
- CCHCR1 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCL22 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCN5 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CCSER1 | c.2654A>T p.H885L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CD276 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CD300C | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); called by muse, mutect2
- CDC7 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CDH10 | c.2264C>A p.T755N | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CDH23 | c.5923G>A p.G1975S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK5RAP3 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK5RAP3 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CENPM | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by muse, mutect2
- CEP97 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CERKL | c.1468T>C p.Y490H (on ENST00000339098 / NM_001030311.2; = p.Y464H on NM_201548.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- CERS6 | c.290A>T p.K97M | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP46 | c.4568A>T p.E1523V | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CHCHD1 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CHD7 | c.6170G>T p.R2057L | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CHRM3 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CNGB1 | c.3092T>A p.I1031K | Missense Mutation (SNP) | VAF 61/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNKSR2 | c.2146-1G>T p.X716_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- CNOT1 | c.2891+1G>A p.X964_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- CNOT3 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2
- COL11A1 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL11A1 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL16A1 | c.2563A>T p.T855S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2
- COL18A1 | c.1960G>T p.E654* (on ENST00000359759 / NM_130444.3; = p.E419* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 36/219 reads (16%) | called by muse, mutect2, varscan2
- COL1A2 | c.2621G>C p.G874A | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL22A1 | c.4850C>A p.A1617D | Missense Mutation (SNP) | VAF 57/428 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL5A1 | c.3582T>G p.S1194= | Splice Region (SNP) | VAF 38/287 reads (13%) | called by muse, mutect2, varscan2
- COL6A1 | c.2761G>T p.G921C | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- CPB2 | c.98del p.P33Lfs*25 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- CPD | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- CRB1 | c.1597G>C p.V533L | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- CRX | c.108del p.R37Gfs*38 | Frame Shift Del (DEL) | VAF 50/258 reads (19%) | called by mutect2, varscan2
- CSGALNACT2 | c.185A>C p.Q62P | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CSMD2 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CSRNP3 | c.787C>A p.R263S | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CT55 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- CUBN | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CXCL11 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CXCR4 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 72/530 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CYP11A1 | c.989C>A p.T330K | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYP2W1 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYSLTR1 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DAAM2 | c.2415A>G p.I805M | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2
- DAAM2 | c.2417G>T p.G806V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DKC1 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 96/546 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- DMD | c.6533C>A p.A2178D | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DMRTA1 | c.1154C>A p.T385K | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DNAH17 | c.10371del p.S3458Vfs*3 | Frame Shift Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- DNAH6 | c.12289C>T p.Q4097* | Nonsense Mutation (SNP) | VAF 23/194 reads (12%) | called by muse, mutect2, varscan2
- DNAH7 | c.7284T>A p.D2428E | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DNAH7 | c.6809T>G p.F2270C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DNAI4 | c.2113G>T p.G705C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); called by muse, mutect2
- DNAJC17 | c.600+7C>A | Splice Region (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- DOCK11 | c.4755G>T p.M1585I | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DOCK7 | c.4174A>G p.M1392V (on ENST00000635253 / NM_001367561.1; = p.M1361V on NM_033407.3) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DPF3 | c.1137G>T p.*379Yext*? | Nonstop Mutation (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2, varscan2
- DRGX | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2
- DTX2 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.21); called by mutect2, varscan2
- DUSP11 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DYSF | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- EEF1G | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 43/342 reads (13%) | called by muse, mutect2, varscan2
- EFCAB8 | c.2050C>A p.Q684K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EIF4G1 | c.235del p.H79Mfs*9 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- ELAVL4 | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by mutect2, varscan2
- ELMO2 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- EML2 | c.1906A>C p.T636P | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- EML5 | c.2517C>A p.H839Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHB2 | c.3092G>T p.R1031M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | PolyPhen benign (0.133); called by muse, mutect2, varscan2
- EPHB6 | c.312_313del p.I105Sfs*31 | Frame Shift Del (DEL) | VAF 64/426 reads (15%) | called by pindel, varscan2
- EPHB6 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 83/657 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPRS1 | c.4042A>T p.N1348Y | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ERCC6 | c.2924+1G>T p.X975_splice | Splice Site (SNP) | VAF 84/601 reads (14%) | called by muse, varscan2
- EXOC6B | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FADS1 | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FAM120AOS | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM135B | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAM163B | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM171A2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171A2 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47A | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FAM47C | c.522A>T p.E174D | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- FAM89A | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FANK1 | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAP | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by mutect2, varscan2
- FARP2 | c.868G>T p.G290* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2
- FBLN2 | c.2498C>A p.S833Y | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO40 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCRL4 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- FCRL5 | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.4913A>G p.E1638G (on ENST00000623019; = p.E1611G on NM_001293083.2) | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FGF6 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FLNA | c.3013G>C p.A1005P | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FOXD4L1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 79/607 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- FRMPD2 | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FRYL | c.1385A>C p.Q462P | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FSIP1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- FSIP2 | c.14449A>G p.T4817A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.398); called by muse, mutect2
- FTSJ1 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- FYN | c.1461C>G p.C487W | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2
- FYN | c.1460G>T p.C487F | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2
- GALNTL5 | c.1032G>C p.W344C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- GAS2L2 | c.1541C>A p.T514K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- GATA1 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- GCN1 | c.3664G>A p.V1222I | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GDAP1L1 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GEMIN8 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 63/350 reads (18%) | called by muse, mutect2, varscan2
- GFRA1 | c.620A>C p.H207P | Missense Mutation (SNP) | VAF 61/529 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GFRA1 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 63/538 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GJA10 | c.1028G>T p.S343I | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNB5 | c.588C>A p.N196K (on ENST00000261837 / NM_016194.4; = p.N154K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNL2 | c.1078A>T p.I360F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 63/640 reads (10%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- GPATCH1 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, varscan2
- GPC2 | c.1637A>G p.Y546C | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- GPNMB | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.163); called by muse, mutect2
- GPR158 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GPR174 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.296); called by muse, mutect2
- GPX6 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GRIK3 | c.2711G>C p.G904A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GRIN2A | c.3296G>T p.S1099I | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); called by muse, varscan2
- GRM8 | c.849T>A p.N283K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GSC | c.701A>T p.K234M | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- GSTA5 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 43/546 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HACD4 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HCFC1 | c.5179G>T p.A1727S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEPACAM | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 63/388 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPHL1 | c.1969C>A p.H657N | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2
- HIC1 | c.1815_1831del p.N605Kfs*181 (on ENST00000322941 / NM_001098202.1; = p.N586Kfs*181 on NM_006497.4) | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- HIPK2 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMCN1 | c.2473A>G p.K825E | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, varscan2
- HOXA7 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2
- HSPA8 | c.1886G>T p.G629V | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HTR1A | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HUWE1 | c.8588C>A p.A2863D | Missense Mutation (SNP) | VAF 61/411 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HUWE1 | c.6030+1G>T p.X2010_splice | Splice Site (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- ICE1 | c.11_12insT p.E5Rfs*28 | Frame Shift Ins (INS) | VAF 33/156 reads (21%) | called by mutect2, pindel, varscan2
- IFT80 | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGF2BP1 | c.280T>A p.W94R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- IGHV1-18 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 67/422 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IGHV1-58 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 83/673 reads (12%) | called by muse, mutect2, varscan2
- IGKV1-17 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 66/555 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- IGKV1-17 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 65/553 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- IGKV3D-20 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- IGSF3 | c.1934G>T p.C645F (on ENST00000369486 / NM_001007237.3; = p.C665F on NM_001542.4) | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IKZF1 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 29/307 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2
- IKZF5 | c.579A>T p.R193S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL9R | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- INF2 | c.1587del p.V530Wfs*28 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- IQSEC2 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IQSEC3 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- IRX4 | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ITGA8 | c.2850G>C p.R950S | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPR1 | c.2539G>T p.D847Y (on ENST00000354582; = p.D832Y on NM_002222.7) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITPR2 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KALRN | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA5 | c.1246C>A p.H416N | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH8 | c.2593C>A p.Q865K | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2
- KCNK18 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 43/252 reads (17%) | called by muse, mutect2, varscan2
- KCTD5 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD8 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDR | c.3778A>T p.S1260C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA0895 | c.801T>G p.Y267* (on ENST00000297063 / NM_001100425.2; = p.Y216* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 32/272 reads (12%) | called by muse, mutect2, varscan2
- KIAA1109 | c.12262G>C p.G4088R | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIAA1210 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); called by muse, mutect2
- KIF3B | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KIF7 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIR2DL4 | c.432del p.T145Lfs*11 (on ENST00000396284; = p.T106Lfs*11 on NM_001080770.2) | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by pindel, varscan2
- KIR3DL2 | c.1105+1G>T p.X369_splice | Splice Site (SNP) | VAF 47/233 reads (20%) | called by muse, mutect2, varscan2
- KIRREL1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KPTN | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT1 | c.1313A>T p.K438M | Missense Mutation (SNP) | VAF 85/496 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP10-10 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- KRTAP9-8 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 70/674 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, varscan2
- L1CAM | c.2998G>T p.G1000C | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.1728A>T p.Q576H | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LCE4A | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 32/295 reads (11%) | called by muse, mutect2, varscan2
- LDHA | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LENG9 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LGI1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 63/525 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGI1 | c.1132A>G p.R378G | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIG3 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LILRB1 | c.958C>A p.L320M (on ENST00000427581; = p.L284M on NM_006669.6) | Missense Mutation (SNP) | VAF 68/460 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRIT1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRP1 | c.8935A>G p.T2979A | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRP1B | c.13267G>T p.G4423C | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYST | c.11204G>A p.S3735N | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LZTS2 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 42/212 reads (20%) | called by muse, mutect2, varscan2
- MAB21L4 | c.1054G>T p.G352C (on ENST00000388934 / NM_001085437.3; = p.G184C on NM_024861.4) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MAGEB6 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGEC3 | c.1359G>T p.R453S | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); called by mutect2, varscan2
- MAGEE1 | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 19/231 reads (8%) | called by muse, mutect2
- MAGI1 | c.3352G>T p.E1118* (on ENST00000402939 / NM_001033057.2; = p.E1147* on NM_004742.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- MAP3K19 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2
- MAP4K4 | c.3013G>C p.D1005H (on ENST00000347699 / NM_001242559.2; = p.D923H on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAPRE2 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- MBD4 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MBL2 | c.722T>A p.L241Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MCCC1 | c.447T>A p.F149L | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2 | c.2287G>T p.V763F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MDGA2 | c.3030G>T p.W1010C (on ENST00000399232 / NM_001113498.2; = p.W712C on NM_182830.4) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MECOM | c.558G>T p.K186N (on ENST00000468789 / NM_001105078.4; = p.K374N on NM_004991.4) | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MECOM | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- MECP2 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- MEGF8 | c.7424C>G p.T2475S (on ENST00000251268 / NM_001271938.2; = p.T2408S on NM_001410.3) | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MFN1 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MID1 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 57/489 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MKLN1 | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MKS1 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 70/462 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MME | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MOBP | c.478C>T p.P160S (on ENST00000420739; = p.P184S on NM_001278322.2) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | PolyPhen benign (0.025); called by muse, varscan2
- MRC1 | c.125G>T p.S42I | Missense Mutation (SNP) | VAF 76/691 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MROH2B | c.2807C>A p.A936D | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MRPL47 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MRPS30 | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MSL3 | c.1293G>T p.W431C (on ENST00000312196 / NM_078629.4; = p.W265C on NM_006800.4) | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSRB2 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTBP | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MTOR | c.4431G>A p.M1477I | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC6 | c.1537C>A p.P513T | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MVP | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MYCT1 | c.689dup p.A231Gfs*30 | Frame Shift Ins (INS) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- MYH2 | c.1766T>A p.V589E | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MYO15A | c.3428A>T p.Q1143L | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MYO18B | c.6384G>T p.W2128C | Missense Mutation (SNP) | VAF 49/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO1D | c.2086del p.Q696Rfs*4 | Frame Shift Del (DEL) | VAF 26/274 reads (9%) | called by mutect2, pindel
- MYO3A | c.3380A>G p.K1127R | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, varscan2
- NDST4 | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NDUFAF1 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2
- NEFL | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NFASC | c.1436A>G p.H479R (on ENST00000339876 / NM_001378329.1; = p.H490R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/607 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIBAN1 | c.2288G>T p.C763F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIBAN1 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2
- NIPBL | c.2279A>T p.H760L | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); called by mutect2, varscan2
- NKAIN4 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.577); called by muse, varscan2
- NLRP13 | c.2790-2A>T p.X930_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- NOBOX | c.1493C>A p.S498* | Nonsense Mutation (SNP) | VAF 39/225 reads (17%) | called by muse, mutect2, varscan2
- NPAS4 | c.1168C>A p.L390I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN1 | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NSA2 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- NSUN6 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP98 | c.3291G>T p.M1097I (on ENST00000359171 / NM_001365126.1; = p.M1080I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.16372G>T p.A5458S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OBSL1 | c.3631A>T p.R1211W | Missense Mutation (SNP) | VAF 58/373 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OGFR | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10A7 | c.679A>T p.R227W | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR10D3 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10G4 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR10X1 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- OR1S2 | c.94A>T p.N32Y | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, varscan2
- OR2B6 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR2L2 | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR2T11 | c.524dup p.C176Lfs*2 | Frame Shift Ins (INS) | VAF 35/148 reads (24%) | called by mutect2, pindel, varscan2
- OR2T27 | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR2T6 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- OR4A16 | c.401T>A p.M134K | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OR4C13 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- OR4K17 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by mutect2, varscan2
- OR4K2 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- OR5D18 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- OR5W2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR6N2 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OR8D1 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- OR8H1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- OR8I2 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, varscan2
- OTOG | c.696-1G>T p.X232_splice | Splice Site (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- OTUD6A | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PABPC5 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAGE5 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PAK2 | c.480G>C p.K160N | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PANX3 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- PAPOLA | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, varscan2
- PASD1 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.866); called by muse, varscan2
- PCDH11X | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PCDH15 | c.4808C>A p.T1603N | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHAC2 | c.1640T>A p.V547E | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- PCDHGA5 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PCDHGB1 | c.1641G>T p.L547F | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PCDHGB2 | c.1744G>C p.A582P | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PCNT | c.8525C>T p.T2842I | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCSK7 | c.1225G>C p.A409P | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDCD7 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- PDZK1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- PEG3 | c.3481C>A p.Q1161K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.894); called by muse, mutect2
- PHKA2 | c.3032C>A p.T1011N | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PIK3R4 | c.2487A>T p.R829S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PIM2 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLD5 | c.781C>A p.L261I (on ENST00000442594; = p.L199I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.759); called by muse, mutect2
- PLEKHA2 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH2 | c.4454G>T p.R1485I | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLPPR5 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 160/541 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLSCR5 | c.238C>A p.L80I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLXNB3 | c.1319C>A p.P440H | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- POM121L2 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- POU3F2 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- POU4F2 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU6F2 | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PRAMEF11 | c.152G>C p.C51S | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PREX1 | c.4891G>T p.A1631S | Missense Mutation (SNP) | VAF 44/501 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PRH2 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, varscan2
- PRKAR2B | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKAR2B | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR23B | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PRSS37 | c.398T>A p.L133H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- PRUNE2 | c.1675G>C p.G559R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- PTCHD1 | c.1568G>T p.S523I | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- PTGDR2 | c.388T>C p.C130R | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PTPRF | c.5641A>G p.M1881V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RADX | c.837G>C p.W279C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RALYL | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RAP1GDS1 | c.178C>G p.P60A (on ENST00000408927 / NM_001100427.2; = p.P61A on NM_021159.5) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAPGEF2 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RASSF2 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAVER2 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM19 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RBMX2 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.072); called by muse, mutect2
- RDX | c.1685A>T p.Y562F | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS9 | c.1134G>C p.K378N | Missense Mutation (SNP) | VAF 84/565 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RIMBP2 | c.2286G>C p.E762D | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RIPPLY1 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1L1 | c.4950G>C p.E1650D | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.444); called by muse, mutect2
- RSPO4 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 64/349 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RSU1 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2
- RTL9 | c.3976C>A p.P1326T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RTN1 | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.43); called by muse, mutect2
- RTTN | c.3154G>T p.A1052S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.9085G>T p.G3029C | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- RYR2 | c.13270G>T p.A4424S | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RYR3 | c.12058G>T p.V4020L (on ENST00000389232; = p.V4021L on NM_001036.6) | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SCAF11 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SCIN | c.1312T>C p.Y438H (on ENST00000297029 / NM_001112706.3; = p.Y191H on NM_033128.3) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SCML1 | c.890G>T p.S297I (on ENST00000380041 / NM_001037540.3; = p.S270I on NM_006746.6) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCN1A | c.1496A>G p.N499S | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCN2A | c.998A>G p.N333S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCN3A | c.1563C>G p.D521E | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0.005); called by muse, mutect2
- SCN7A | c.1838T>A p.F613Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SCN8A | c.2514G>C p.E838D | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SEC16B | c.1366del p.E456Kfs*7 | Frame Shift Del (DEL) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- SEC23IP | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- SEPTIN6 | c.471del p.T158Rfs*5 | Frame Shift Del (DEL) | VAF 38/203 reads (19%) | called by mutect2, pindel, varscan2
- SERPINA4 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 88/619 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SESN3 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SETD1B | c.3686G>C p.G1229A | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3BGRL | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SH3GL3 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3RF3 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SHANK2 | c.1299G>T p.W433C | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SIPA1L1 | c.3974del p.D1325Afs*45 | Frame Shift Del (DEL) | VAF 37/275 reads (13%) | called by mutect2, pindel, varscan2
- SIRT1 | c.901_909del p.Y301_R303del | In Frame Del (DEL) | VAF 22/176 reads (13%) | called by mutect2, pindel
- SLC14A2 | c.2156T>C p.F719S | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SLC16A2 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC18A2 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- SLC27A2 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLC28A1 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC44A5 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC4A1 | c.2457C>A p.H819Q | Missense Mutation (SNP) | VAF 73/468 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- SLC6A19 | c.1799A>G p.Y600C | Missense Mutation (SNP) | VAF 242/843 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SLC7A2 | c.1003G>A p.G335S (on ENST00000494857 / NM_001370338.1; = p.G375S on NM_003046.6) | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO2A1 | c.610T>A p.S204T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLCO5A1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLIT1 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLIT3 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SMARCA1 | c.2381C>A p.P794Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); called by mutect2, varscan2
- SMOX | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SNRPN | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SNX11 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SP140L | c.1209G>T p.L403F | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SP140L | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPDYE6 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 91/737 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- SPHKAP | c.3152A>T p.E1051V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SPHKAP | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPR | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SPTBN1 | c.4327G>T p.A1443S | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SRFBP1 | c.198+1G>T p.X66_splice | Splice Site (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.8642G>A | Splice Region (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- STAG1 | c.3065+1G>T p.X1022_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- STARD8 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 73/397 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK31 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2
- STK31 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.203); called by muse, mutect2
- STK32C | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 62/229 reads (27%) | PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SUSD5 | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SYNE2 | c.14122G>T p.E4708* | Nonsense Mutation (SNP) | VAF 34/271 reads (13%) | called by mutect2, varscan2
- SYTL4 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.88); PolyPhen benign (0.005); called by muse, mutect2
- SYTL5 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TAF2 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TAPT1 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R14 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS2R16 | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D22B | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- TBC1D23 | c.74_79del p.A25_L26del | In Frame Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- TBC1D4 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 137/504 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TBPL2 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TCEAL4 | c.149A>T p.K50M | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TECTB | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.7266G>T p.K2422N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TENM1 | c.5887G>T p.G1963W | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM3 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TEX11 | c.1717G>T p.E573* (on ENST00000344304; = p.E558* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- TF | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 56/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- THOC2 | c.1429-1G>T p.X477_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- THPO | c.629G>T p.G210V (on ENST00000649095 / NM_001290003.1; = p.G70V on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/433 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TIMD4 | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE1 | c.689A>T p.D230V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TLR7 | c.1139A>T p.Y380F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TLX1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.074); called by muse, mutect2
- TM4SF5 | c.180A>T p.V60= | Splice Region (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- TMEM132C | c.3190C>G p.P1064A | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMEM201 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 56/386 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNR | c.1106T>A p.L369H | Missense Mutation (SNP) | VAF 70/574 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM51GP | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TRPM3 | c.4068G>T p.K1356N (on ENST00000357533 / NM_001366142.2; = p.K1211N on NM_020952.6) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); called by muse, varscan2
- TTI1 | c.2599A>T p.M867L | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TTLL6 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.36251A>T p.N12084I (on ENST00000591111; = p.N4660I on NM_003319.4) | Missense Mutation (SNP) | VAF 45/257 reads (18%) | PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TTN | c.9791del p.G3264Efs*35 (on ENST00000591111; = p.G3218Efs*35 on NM_003319.4) | Frame Shift Del (DEL) | VAF 22/219 reads (10%) | called by mutect2, pindel, varscan2
- TTN | c.3205C>A p.L1069I (on ENST00000591111; = p.L1023I on NM_003319.4) | Missense Mutation (SNP) | VAF 47/323 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3E | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBB1 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TXLNG | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- UBASH3A | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2L3 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBE3B | c.100G>T p.V34F | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- UGP2 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- UNC80 | c.1081C>G p.H361D | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- USH2A | c.11719G>A p.A3907T | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- USO1 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USO1 | c.2321A>T p.Q774L | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP51 | c.1751C>A p.T584K | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VASP | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- VEGFC | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13A | c.7279T>C p.Y2427H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- WDR17 | c.2851G>T p.A951S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- WDR37 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR44 | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- WNK2 | c.1961C>G p.P654R | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WWC2 | c.2281A>T p.T761S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.028); called by muse, mutect2
- ZACN | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- ZAN | c.5318G>T p.C1773F | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZC3H12C | c.2198A>T p.H733L | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZCCHC18 | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ZDHHC17 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.346); called by muse, mutect2
- ZFHX4 | c.2520del p.D841Tfs*4 | Frame Shift Del (DEL) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- ZNF106 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- ZNF131 | c.1557G>T p.Q519H (on ENST00000509156 / NM_001330707.2; = p.Q485H on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZNF23 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF236 | c.2406C>A p.S802R | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZNF280B | c.589G>T p.G197* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
373 further variants in this file (12 protein-altering or splice-affecting, 203 silent, 158 other) are not listed here.
